Gene-level copy-number profile of tumor specimen TCGA-IB-8127-01A from TCGA case TCGA-IB-8127, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 59.3 years (21,676 days).
Specimen TCGA-IB-8127-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PAAD.644240ec-e346-4391-be88-1b3f4ef12b7f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-IB-8127-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ed27efd4-7c7c-4f47-a730-cddc8c9656f7

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,430; copy number 2: 11,986; copy number 3: 15,262; copy number 4: 27,241; copy number 5: 1,443; copy number 6: 2,208; copy number 7: 176; copy number 8: 12; copy number 9: 27; copy number 11: 29.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-IB-8127-01A-11D-2392-01): tumor purity 0.35, ploidy 3.35, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 56 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:13,756,027–17,476,879, 56 genes, copy number 9–11 (within-gene range 4–11): CENPUP1, AC013828.1, LINC02548, AC027779.1, LINC02545, RNA5SP331, LINC02683, SPON1, RNA5SP332, SPON1-AS1, RRAS2, AC018523.1, COPB1, RNU7-49P, AC018523.2, PSMA1, PDE3B, MORF4L1P3, CYP2R1, CALCB, CALCP, CALCA, OR7E41P, INSC, AC104361.1, LINC02751, AC073172.1, AC087379.2, AC087379.1, AC009869.1, LINC02682, SOX6, MIR6073, AC103794.1, AKR1B1P3, RN7SL188P, C11orf58, PLEKHA7, RN7SKP90, AC116533.1, OR7E14P, RPS13, SNORD14A, SNORD14B, PIK3C2A, RNU6-593P, AC126389.1, AC107956.2, NUCB2, AC107956.1, AC124798.2, NCR3LG1, AC124798.1, KCNJ11, ABCC8, SDHCP4.

Autosomal genes at a single copy (total copy number 1): 1,430. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
